Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAID, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAID-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 2.5 cm; no invasion of rete testis; no angio-invasion; lymphatic invasion present; the tunica albuginea and epididymis are not penetrated. Tumor confined to testis in available slides.

Date of procurement (= date of orchidectomy):

ICD-O 3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9
JAS 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 918e6f8d-808c-4746-948e-1f4f9e23d437 (TCGA-2G-AAID-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).